Gene-level copy-number profile of tumor specimen ALCH-B025-TTP1-A from ALCHEMIST case ALCH-B025, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,849 days).
Specimen ALCH-B025-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5e92eef8-265d-4112-9a18-f2d2c0744f05.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B025-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/dfb4e09c-226c-4d51-93bc-838f883f3454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 8,710; copy number 2: 46,025; copy number 3: 3,542; copy number 4: 106; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,279,125–13,285,174, 2 genes: RNU6-771P, PRAMEF8.
- chr6:167,146,414–167,196,913, 3 genes: TCP10L2, GPR31, AL121935.3.
- chr9:135,693,407–135,795,508, 2 genes: SOHLH1, KCNT1.
- chr14:104,137,150–104,180,894, 2 genes: AL359399.1, KIF26A.
- chr16:88,881,038–88,887,136, 1 gene (within-gene range 0–2): AC092384.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:917,287–921,005, 1 gene, copy number 5: KISS1R.

Autosomal genes at a single copy (total copy number 1): 6,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
